Somatic mutation profile of tumor specimen MMRF_1650_2_BM_CD138pos (aliquot MMRF_1650_2_BM_CD138pos_T1_KHS5U_L13312) from MMRF case MMRF_1650, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 82.9 years (30,292 days).
Specimen MMRF_1650_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e19b0e96-f5a9-46cb-84c3-46ef326e2993.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1650_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1650_1_PB_Whole_C2_KBS5U_L06500; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0fb9de21-9eb7-4164-b638-650bf310414c

The open-access MAF lists 117 somatic variants for this specimen: 42 protein-altering or splice-affecting, 17 silent, 58 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, 3'UTR 31, Intron 18, Silent 17, 3'Flank 4, 5'UTR 3, Nonsense Mutation 2, Splice Site 1, Translation Start Site 1, Frame Shift Del 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 64/149 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- AGAP2 | c.3017C>T p.T1006M (on ENST00000547588 / NM_001122772.2; = p.T650M on NM_014770.4) | Missense Mutation (SNP) | VAF 115/252 reads (46%) | SIFT tolerated (0.88); PolyPhen benign (0.007); catalogued as rs768766650; called by muse, mutect2, varscan2
- CDK11A | c.365G>A p.R122Q (on ENST00000378633 / NM_001313896.2; = p.R132Q on NM_024011.4) | Missense Mutation (SNP) | VAF 67/171 reads (39%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.52); catalogued as rs750242434, COSV100651779; called by muse, mutect2, varscan2
- COL6A6 | c.4627G>A p.G1543R | Missense Mutation (SNP) | VAF 64/128 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376262924; called by muse, varscan2
- EGF | c.2248G>A p.G750R | Missense Mutation (SNP) | VAF 63/146 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54484797; called by muse, mutect2, varscan2
- ELP1 | c.573G>A p.W191* | Nonsense Mutation (SNP) | VAF 83/243 reads (34%) | catalogued as rs751308604; called by muse, mutect2, varscan2
- HMCN1 | c.14510G>A p.R4837Q | Missense Mutation (SNP) | VAF 75/141 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.177); catalogued as rs752242653, COSV54888710; called by muse, mutect2, varscan2
- IGKV2-30 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs750905502; called by muse, mutect2, varscan2
- IGLV3-1 | c.65A>C p.E22A | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT tolerated (0.6); PolyPhen benign (0.018); catalogued as rs528877557; called by muse, mutect2, varscan2
- IGLV3-1 | c.136T>A p.L46M | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.199); catalogued as rs374795971; called by muse, varscan2
- IGLV3-1 | c.148T>A p.Y50N | Missense Mutation (SNP) | VAF 76/135 reads (56%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as rs368495152; called by muse, varscan2
- MBTPS1 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 90/122 reads (74%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); catalogued as rs369349224; called by muse, mutect2, varscan2
- MEX3B | c.1373G>C p.R458P | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs200650374, COSV61663150; called by muse, mutect2
- MMP14 | c.238G>T p.A80S | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs971426762; called by muse, mutect2, varscan2
- MROH2B | c.3400G>A p.A1134T | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs752551224, COSV68184661; called by muse, mutect2
- NCAPG2 | c.2293G>T p.E765* | Nonsense Mutation (SNP) | VAF 56/126 reads (44%) | catalogued as COSV51987526; called by muse, mutect2, varscan2
- SEC14L5 | c.1069G>A p.V357I | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs771138868; called by muse, mutect2
- SMURF1 | c.1691G>A p.R564Q | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.017); catalogued as rs182340234; called by muse, mutect2, varscan2
- UBALD2 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.148); catalogued as rs1249640447; called by muse, mutect2
- ACTN1 | c.7C>A p.H3N | Missense Mutation (SNP) | VAF 103/251 reads (41%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD13B | c.1178T>C p.M393T | Missense Mutation (SNP) | VAF 98/222 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CAMK2G | c.1176G>T p.E392D (on ENST00000423381 / NM_001367518.1; = p.E358D on NM_001222.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CATSPERD | c.535G>T p.G179W | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- CYLD | c.464dup p.R156Efs*11 | Frame Shift Ins (INS) | VAF 22/113 reads (19%) | called by mutect2, pindel, varscan2
- EGR4 | c.170G>C p.R57T | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- FHOD3 | c.909C>A p.N303K | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FUBP1 | c.473+2T>A p.X158_splice | Splice Site (SNP) | VAF 10/20 reads (50%) | called by muse, varscan2
- IGHV2-70D | c.243C>G p.S81R | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.021); called by muse, varscan2
- IGHV2-70D | c.143T>G p.L48R | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); called by muse, varscan2
- KCNH4 | c.2510C>T p.T837I | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- KDM3B | c.4579C>A p.L1527I | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- MTF2 | c.673T>C p.W225R | Missense Mutation (SNP) | VAF 52/127 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- OR1D5 | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 35/178 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PDZRN3 | c.972C>G p.F324L | Missense Mutation (SNP) | VAF 122/246 reads (50%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RO60 | c.427A>T p.M143L | Missense Mutation (SNP) | VAF 61/182 reads (34%) | SIFT tolerated (0.93); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SOWAHC | c.713del p.G238Afs*25 | Frame Shift Del (DEL) | VAF 23/45 reads (51%) | called by mutect2, pindel, varscan2
- TENT4B | c.712G>A p.V238M (on ENST00000561678 / NM_001365323.2; = p.V223M on NM_001040284.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM176A | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- TNFAIP8 | c.-66C>T | Splice Region (SNP) | VAF 71/133 reads (53%) | called by muse, mutect2, varscan2
- TPO | c.1980G>C p.Q660H | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UNC80 | c.4369A>T p.M1457L | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- USP48 | c.1360A>G p.M454V | Missense Mutation (SNP) | VAF 63/392 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CATSPERD | c.534T>C p.T178= | Silent (SNP) | VAF 14/51 reads (27%) | called by muse, mutect2, varscan2
- EGFR | c.2382C>A p.P794= | Silent (SNP) | VAF 67/158 reads (42%) | called by muse, mutect2
- GFPT2 | c.1848C>T p.R616= | Silent (SNP) | VAF 43/110 reads (39%) | called by muse, mutect2, varscan2
- H2BC3 | c.261C>A p.R87= | Silent (SNP) | VAF 66/117 reads (56%) | called by muse, mutect2, varscan2
- IGHV2-70D | c.303T>C p.L101= | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as rs1421187044; called by muse, varscan2
- IGHV2-70D | c.219T>C p.D73= | Silent (SNP) | VAF 33/90 reads (37%) | called by muse, varscan2
- IGKJ5 | c.9C>T p.T3= | Silent (SNP) | VAF 85/124 reads (69%) | catalogued as rs375348000; called by muse, varscan2
- IGKJ5 | c.6C>T p.I2= | Silent (SNP) | VAF 82/118 reads (69%) | catalogued as rs367938025; called by muse, varscan2
- JADE2 | c.2193A>T p.P731= | Silent (SNP) | VAF 92/167 reads (55%) | called by muse, mutect2, varscan2
- KLK15 | c.387G>A p.T129= | Silent (SNP) | VAF 36/90 reads (40%) | catalogued as COSV56826959; called by muse, mutect2, varscan2
- MOGAT1 | c.159T>A p.P53= | Silent (SNP) | VAF 16/170 reads (9%) | called by muse, mutect2
- PAX9 | c.126C>A p.I42= | Silent (SNP) | VAF 154/286 reads (54%) | called by muse, mutect2, varscan2
- PSPH | c.579C>T p.F193= | Silent (SNP) | VAF 81/198 reads (41%) | called by muse, mutect2, varscan2
- SIGLEC1 | c.927C>T p.N309= | Silent (SNP) | VAF 94/252 reads (37%) | catalogued as rs771174087, COSV52459748; called by muse, mutect2, varscan2
- SZT2 | c.9213C>T p.L3071= (on ENST00000634258 / NM_001365999.1; = p.L3014= on NM_015284.4) | Silent (SNP) | VAF 23/70 reads (33%) | called by muse, mutect2, varscan2
- TBC1D9 | c.1968C>T p.Y656= | Silent (SNP) | VAF 33/59 reads (56%) | catalogued as rs754059861; called by muse, mutect2, varscan2
- ZNF274 | c.1887C>T p.T629= (on ENST00000610905; = p.T524= on NM_016324.3) | Silent (SNP) | VAF 115/235 reads (49%) | catalogued as rs1227916540, COSV58766601; called by muse, mutect2, varscan2
- AL645922.1 | c.1571-336C>G | Intron (SNP) | VAF 24/75 reads (32%) | catalogued as rs183629312; called by muse, mutect2
- AP001122.1 | n.630T>C | RNA (SNP) | VAF 81/207 reads (39%) | called by muse, mutect2, varscan2
- AP1S3 | c.430-5481G>A | Intron (SNP) | VAF 17/30 reads (57%) | called by muse, varscan2
- APOL4 | c.44+116A>C | Intron (SNP) | VAF 90/244 reads (37%) | called by muse, mutect2, varscan2
- C5orf15 | c.*616_*641del | 3'UTR (DEL) | VAF 8/32 reads (25%) | called by mutect2, pindel
- CADM2 | chr3:86067392 G>A | 3'Flank (SNP) | VAF 19/51 reads (37%) | called by muse, mutect2, varscan2
- CCDC171 | c.3600+8437C>T | Intron (SNP) | VAF 6/18 reads (33%) | called by muse, varscan2
- CCDC68 | chr18:54902793 C>T | 3'Flank (SNP) | VAF 40/68 reads (59%) | called by muse, mutect2, varscan2
- CLCA2 | c.*878C>T | 3'UTR (SNP) | VAF 15/46 reads (33%) | called by muse, mutect2, varscan2
- CLRN1 | c.*4G>T | 3'UTR (SNP) | VAF 110/226 reads (49%) | called by muse, mutect2, varscan2
- CNKSR3 | c.*357G>A | 3'UTR (SNP) | VAF 66/108 reads (61%) | called by muse, mutect2, varscan2
- CNNM4 | c.*1C>T | 3'UTR (SNP) | VAF 63/150 reads (42%) | catalogued as rs759145970; called by muse, mutect2, varscan2
- CNOT6L | c.*6333C>A | 3'UTR (SNP) | VAF 46/119 reads (39%) | called by muse, mutect2, varscan2
- CSPG5 | c.*126G>A | 3'UTR (SNP) | VAF 8/194 reads (4%) | called by muse, mutect2
- DNAJC21 | c.*1399T>G | 3'UTR (SNP) | VAF 31/55 reads (56%) | called by muse, mutect2, varscan2
- DNAJC24 | c.*571A>T | 3'UTR (SNP) | VAF 17/42 reads (40%) | called by muse, mutect2, varscan2
- EPHA5 | c.*1053G>T | 3'UTR (SNP) | VAF 30/70 reads (43%) | called by muse, mutect2, varscan2
- GGT3P | n.834+3260G>C | Intron (SNP) | VAF 7/59 reads (12%) | called by muse, mutect2, varscan2
- GLP2R | c.1056+4239C>T | Intron (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2
- HTR2A | c.-572G>T | 5'UTR (SNP) | VAF 15/32 reads (47%) | called by muse, mutect2
- IGHV1-69D | c.-37T>A | 5'UTR (SNP) | VAF 34/119 reads (29%) | called by muse, mutect2, varscan2
- IL17D | c.*533T>G | 3'UTR (SNP) | VAF 38/75 reads (51%) | called by muse, mutect2, varscan2
- INTS8 | chr8:94822908 G>C | 5'Flank (SNP) | VAF 10/210 reads (5%) | called by muse, mutect2
- LACTB2 | c.286+519C>A | Intron (SNP) | VAF 40/82 reads (49%) | called by muse, mutect2, varscan2
- LIMD2 | c.-50-64C>T | Intron (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2, varscan2
- LRPAP1 | c.*119A>C | 3'UTR (SNP) | VAF 33/88 reads (38%) | called by muse, mutect2, varscan2
- LRRC49 | c.1169+54G>A | Intron (SNP) | VAF 21/53 reads (40%) | called by muse, mutect2, varscan2
- MMP16 | c.*3959G>T | 3'UTR (SNP) | VAF 38/84 reads (45%) | catalogued as rs901055894; called by muse, mutect2, varscan2
- MTPN | c.*2117C>G | 3'UTR (SNP) | VAF 129/292 reads (44%) | called by muse, mutect2, varscan2
- MYO1E | c.-21G>C | 5'UTR (SNP) | VAF 34/63 reads (54%) | called by muse, mutect2, varscan2
- NCAM2 | c.*3217T>A | 3'UTR (SNP) | VAF 27/46 reads (59%) | called by muse, mutect2, varscan2
- NPM1 | chr5:171411163 G>A | 3'Flank (SNP) | VAF 24/57 reads (42%) | called by muse, mutect2, varscan2
- NPSR1 | c.384+1163G>T | Intron (SNP) | VAF 8/111 reads (7%) | called by muse, mutect2
- PAMR1 | c.*414A>T | 3'UTR (SNP) | VAF 29/61 reads (48%) | called by muse, mutect2, varscan2
- PANK1 | c.*698G>A | 3'UTR (SNP) | VAF 68/139 reads (49%) | catalogued as rs1163703022; called by muse, mutect2, varscan2
- PCDH9 | c.*778T>G | 3'UTR (SNP) | VAF 27/61 reads (44%) | called by muse, mutect2, varscan2
- PID1 | chr2:229024846 del TTGA | 3'Flank (DEL) | VAF 28/58 reads (48%) | called by mutect2, pindel, varscan2
- PPFIA3 | c.2835+16C>T | Intron (SNP) | VAF 14/43 reads (33%) | catalogued as rs757682307; called by muse, mutect2, varscan2
- PPP3R2 | c.*2653T>C | 3'UTR (SNP) | VAF 51/118 reads (43%) | called by muse, mutect2, varscan2
- PRDM1 | c.412-356A>T | Intron (SNP) | VAF 137/191 reads (72%) | catalogued as rs561962994, COSV64846086; called by muse, mutect2, varscan2
- PUDP | c.*1268A>G | 3'UTR (SNP) | VAF 42/46 reads (91%) | called by muse, mutect2, varscan2
- PXMP4 | c.*689A>G | 3'UTR (SNP) | VAF 15/51 reads (29%) | called by muse, mutect2, varscan2
- QSOX1 | c.*1871C>G | 3'UTR (SNP) | VAF 66/190 reads (35%) | called by muse, mutect2, varscan2
- RAB2A | c.*2058T>C | 3'UTR (SNP) | VAF 25/61 reads (41%) | catalogued as rs1365117187; called by muse, mutect2, varscan2
- RAB3IP | c.*7348_*7350del | 3'UTR (DEL) | VAF 21/55 reads (38%) | called by mutect2, pindel, varscan2
- RNF121 | c.*324T>G | 3'UTR (SNP) | VAF 19/48 reads (40%) | called by muse, mutect2, varscan2
- SARNP | c.406+78A>G | Intron (SNP) | VAF 13/32 reads (41%) | called by muse, mutect2, varscan2
- SGCD | c.*4597G>A | 3'UTR (SNP) | VAF 8/132 reads (6%) | called by muse, mutect2
- SLC6A16 | c.1941+88T>C | Intron (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2, varscan2
- SLCO1A2 | c.*3195C>T | 3'UTR (SNP) | VAF 33/83 reads (40%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-18533T>A | Intron (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2, varscan2
- ST8SIA6 | c.*736G>A | 3'UTR (SNP) | VAF 19/51 reads (37%) | catalogued as rs1208688856; called by muse, mutect2, varscan2
- SUV39H2 | c.*1684T>C | 3'UTR (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2
- TNS4 | c.*85del | 3'UTR (DEL) | VAF 34/102 reads (33%) | called by mutect2, pindel, varscan2
- TTC22 | c.1020+886C>T | Intron (SNP) | VAF 17/35 reads (49%) | called by muse, mutect2, varscan2
- UGT2A1 | c.715+11176C>T | Intron (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2
- ZNF135 | c.*1138G>A | 3'UTR (SNP) | VAF 22/41 reads (54%) | catalogued as rs527279005, COSV100536669; called by muse, mutect2
- ZNF558 | c.120+20T>G | Intron (SNP) | VAF 62/156 reads (40%) | called by muse, mutect2, varscan2
